Somatic mutation profile of tumor specimen 0DUKHB from CCDI case PBCLJI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.6 years (1,323 days).
Specimen 0DUKHB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73584cce-3dbd-407b-b208-c2e4c8b6ea7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUKIV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28666dab-5e2e-48cb-b438-e87926af1a8d

The open-access MAF lists 26 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, Intron 5, Splice Region 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C6 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 466/2563 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); catalogued as rs373685271; called by muse, mutect2, varscan2
- RPTOR | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 145/1843 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV60808647; called by muse, mutect2
- ANO2 | c.1747A>G p.I583V (on ENST00000356134 / NM_001278597.3; = p.I587V on NM_001278596.3) | Missense Mutation (SNP) | VAF 626/2079 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- FAM24B | c.260G>C p.C87S | Missense Mutation (SNP) | VAF 480/1186 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 90/3194 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- MBD6 | c.2407-3C>G | Splice Region (SNP) | VAF 104/1359 reads (8%) | called by muse, mutect2
- OR2G6 | c.176T>C p.M59T | Missense Mutation (SNP) | VAF 597/2018 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PTGER4 | c.1307T>C p.I436T | Missense Mutation (SNP) | VAF 516/1608 reads (32%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RBBP4 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 212/1187 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TEK | c.3074G>A p.G1025D | Missense Mutation (SNP) | VAF 113/971 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 62/2088 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- TTC24 | c.1498G>T p.A500S | Missense Mutation (SNP) | VAF 230/970 reads (24%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GABRR1 | c.1029C>T p.A343= | Silent (SNP) | VAF 453/3462 reads (13%) | catalogued as rs756314695; called by muse, mutect2, varscan2
- KLHL1 | c.1395A>G p.G465= | Silent (SNP) | VAF 407/1437 reads (28%) | called by muse, mutect2, varscan2
- NBEAL2 | c.2664C>T p.C888= | Silent (SNP) | VAF 391/1427 reads (27%) | catalogued as rs780626024, COSV99436613; called by muse, mutect2, varscan2
- NCMAP | c.126C>A p.I42= | Silent (SNP) | VAF 152/1482 reads (10%) | catalogued as COSV65556918; called by muse, mutect2, varscan2
- OR5AP2 | c.738C>A p.T246= | Silent (SNP) | VAF 134/1600 reads (8%) | catalogued as COSV57257713; called by muse, mutect2
- SCEL | c.1737G>A p.V579= (on ENST00000349847 / NM_144777.3; = p.V559= on NM_003843.4) | Silent (SNP) | VAF 394/1616 reads (24%) | called by muse, mutect2, varscan2
- ZNF775 | c.1020G>A p.P340= | Silent (SNP) | VAF 498/2515 reads (20%) | catalogued as COSV61613989; called by muse, mutect2, varscan2
- ADAD2 | c.734-26G>T | Intron (SNP) | VAF 764/1943 reads (39%) | called by muse, mutect2, varscan2
- ARR3 | c.1076+72A>G | Intron (SNP) | VAF 332/773 reads (43%) | catalogued as COSV99333457; called by muse, mutect2, varscan2
- DDTL | c.*25C>T | 3'UTR (SNP) | VAF 89/864 reads (10%) | catalogued as COSV99303759; called by muse, mutect2, varscan2
- GPX5 | c.88-31C>G | Intron (SNP) | VAF 129/556 reads (23%) | called by muse, mutect2, varscan2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 6/82 reads (7%) | catalogued as COSV55814242; called by muse, mutect2
- SAMD4A | c.2045-175G>C | Intron (SNP) | VAF 220/873 reads (25%) | called by muse, mutect2, varscan2
- TIMM50 | chr19:39480737 G>A | 5'Flank (SNP) | VAF 340/1177 reads (29%) | catalogued as rs778353895, COSV100068083; called by muse, mutect2, varscan2
